Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4H0, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4H0-01A (Primary Tumor).

[page 1 of 2]
Stomach, total gastrectomy :

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(-)/Muc6(-)/CD10(-)/cERB2(-).Null type)

1. Location : upper third to middle third, center at body, greater curvature

2. Gross type : Borrmann type 4 (diffusely infiltrating)

3. Histologic type : tubular adenocarcinoma, poorly differentiated(non-solid type)

<Addendum>

Final diagnosis: stomach adenocarcinoma, diffuse type.

*pn update/confirmation
by TSS.*

4. Histologic type by Lauren : diffuse

5. Growth pattern: diffusely infiltrative growth pattern

6. Size : 15.0x12.0 cm

7. Depth of invasion : invades serosa (pT4a)

8. Resection margin: free from carcinoma

safety margin: distal 9.0 cm, proximal 3.0 cm, anvil ring: no tumor

9. Lymph node metastasis :

metastasis to 49 out of 89 regional lymph nodes (pN3b)

(lesser curvature 16/29 , greater curvature 31/53 , LN 1/6 , #10 LN 1/1)

10. Lymphatic invasion : present, moderate

11. Venous invasion : not identified

12. Perineural invasion : present, moderate

13. Associated findings : peritumoral lymphocytic infiltration, mild

intratumoral neutrophilic infiltration, mild

Small intestine, jejunum, resection:

No tumor.

*Dx discrepancy from attached
10/9/12
lw*

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

ICD-O-3

adenocarcinoma, diffuse type 8145/3

Site: Stomach, body C16.2

lw 9/27/12

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis from a pathology report is inconsistent with the diagnosis selected on the TCGA Case Quality Control Form.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By

Diagnostic Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Tubular adenocarcinoma- diffuse type	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach adenocarcinoma- diffuse type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy Between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	According to the original pathology report, this tumor is described as a poorly-differentiated tubular adenocarcinoma. In addendum, we clarified the final diagnosis as an stomach adenocarcinoma, diffuse type.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 50e2ba65-8d14-4ede-a38e-9102d231fde8 (TCGA-HU-A4H0.80481900-C013-4252-9BD4-3F59D4B1B06C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).